TCGA case TCGA-HS-A5N9 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2948d657-e5dd-4d6e-91b5-88c54f73ac31

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 58 years; Vital status: Alive.

Diagnoses (1; GDC holds 3 diagnosis records for this case, 2 of them empty or duplicates of those shown)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 58.8 years (21,463 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4.7; Tumor length measurement: 13; Tumor width measurement: 8.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 50; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 13.

Follow-up (2 entries)
- Days to follow up: 1,257 days (3.4 years); Disease response: Tumor Free.
- Days to follow up: 1,585 days (4.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 39.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HS-A5N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 960 mg.
  Slide TCGA-HS-A5N9-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HS-A5N9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HS-A5N9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Margin status: Negative; Tumor total necrosis: Extensive Necrosis (>50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 42; Days from index date to pharmaceutical treatment ended: 91; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 49; Days from index date to pharmaceutical treatment ended: 91; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Other malignancy form 1: Malignancy type: Prior Malignancy.
- Other malignancy form 1, Surgery: Other malignancy surgery type: hemithyroidectomy.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Systemic.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Colon.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,585 days; disease-specific survival: no event (censored), 1,585 days; disease-free interval: no event (censored), 1,585 days; progression-free interval: no event (censored), 1,585 days.
